Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8682, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8682-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

Asterand Case ID	OpenClinica ID	Excision date	Gross Description
			Tumor is located in antrum, there is an ulcerated tumor with 3x4x1.5cm in size, firm and myxoid gray surface.

[page 2 of 3]
Microscopic Description	Diagnosis Details	Comments
Mucosa is ulcerated. The tumor is composed of opened and mildly stratified glands containing mucin, or pools of extracellular mucin that contain malignant epithelium as cord or acinar structures. Tumor cells are mildly stratified and have scant cytoplasm. Tumor in invasion in serosa. Nuclei are hyperchromatic and irregular enlarged with prominent nucleoli. Mitoses are present. Stroma is invasion of inflammatory cells.	Mucinous Adenocarcinoma, infiltrating serosa.	

[page 3 of 3]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Antrum

Tumor size: 3 x 4 x 1.5 cm

Tumor features: Ulcerated

Histologic type: Mucinous adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 0/5 positive for metastasis

(Adjacent lymph node 0/5)

Lymphatic invasion: Present

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 9de2ef49-2220-4f94-aabf-6c80190d03e3 (TCGA-BR-8682.D788C666-1194-492C-A019-2B5C7BE555D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).